Surgical pathology report (de-identified scan), TCGA case TCGA-14-1450, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1450-01B (Primary Tumor).

At: [REDACTED]

Accession Number: [REDACTED]

Financial Number: [REDACTED]

Date Collected: [REDACTED]

Date Received: [REDACTED]

Room/Bed: [REDACTED]

PT: [REDACTED]

Admitting Physician: [REDACTED]

Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT HEMISPHERIC BRAIN TUMOR, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. LEFT HEMISPHERIC BRAIN TUMOR, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).

TCGA-14-1450

SPECIMEN:

1. Left hemispheric brain tumor.
2. Left hemispheric brain tumor.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Left parietal craniotomy for tumor. Brain tumor.

GROSS DESCRIPTION:

Specimen #1 is received fresh for intraoperative consultation, it is labeled with the patient's name and medical record number. The specimen consists of multiple tan-red, soft tissue fragments measuring in aggregate, 2.8 x 1.0 x 0.7 cm. A portion of the specimen is frozen for intraoperative consultation and the remainder of that cryoblock is submitted in cassette "FS1A." The remainder of the specimen is submitted in cassette "1B."

Specimen #2 is labeled "left hemisphere brain tumor." The specimen consists of aggregates of tan-brown tissue measuring in aggregate, 2.2 x 1.6 x 0.4 cm. The specimen is submitted entirely in cassette "2A."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: LEFT HEMISPHERE, BRAIN LESION (FROZEN SECTION, TOUCH PREPARATION):
ASTROCYTIC NEOPLASM.

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Source: NCI Genomic Data Commons file b1e51d9e-6237-4e0e-99eb-6ebbf355d563 (TCGA-14-1450.C8086688-B70D-4B74-BD4D-9CC2568DC76B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).